Somatic mutation profile of tumor specimen TCGA-E1-A7Z4-01A (aliquot TCGA-E1-A7Z4-01A-11D-A34J-08) from TCGA case TCGA-E1-A7Z4, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Astrocytoma, NOS; Tissue or organ of origin: Cerebrum; Tumor grade: G2; Age at diagnosis: 35.2 years (12,849 days).
Specimen TCGA-E1-A7Z4-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 12070316-f519-4fbb-935f-8cf18bd6c9e7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-E1-A7Z4-10A (Blood Derived Normal), aliquot TCGA-E1-A7Z4-10A-01D-A34M-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7dd3b944-9b09-41e1-bb15-8fc9cf48064e

The open-access MAF lists 19 somatic variants for this specimen: 15 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 11, Silent 4, Nonsense Mutation 2, Frame Shift Del 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 42/107 reads (39%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.635_636del p.F212Sfs*3 | Frame Shift Del (DEL) | VAF 46/67 reads (69%) | catalogued as rs864309495; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- AHNAK | c.11887G>A p.V3963I | Missense Mutation (SNP) | VAF 30/570 reads (5%) | SIFT tolerated (0.69); PolyPhen benign (0.003); catalogued as rs201064254, COSV57215242; called by muse, mutect2
- ATRX | c.2186C>G p.S729* | Nonsense Mutation (SNP) | VAF 90/134 reads (67%) | catalogued as COSV100971147, COSV64877344; called by muse, mutect2, varscan2
- CCDC114 | c.790G>A p.V264M | Missense Mutation (SNP) | VAF 14/133 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs371123768; called by muse, mutect2
- CHRND | c.88C>T p.R30W | Missense Mutation (SNP) | VAF 38/98 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.625); catalogued as rs1047325384, COSV51317651; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CLMN | c.781C>G p.P261A | Missense Mutation (SNP) | VAF 47/104 reads (45%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as rs1322885834, COSV100112649; called by muse, mutect2, varscan2
- ENOSF1 | c.1224A>G p.I408M (on ENST00000340116 / NM_001354066.2; = p.I374M on NM_017512.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 35/95 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs1470643048, COSV99201107; called by muse, mutect2, varscan2
- KIF27 | c.775G>T p.E259* | Nonsense Mutation (SNP) | VAF 6/147 reads (4%) | catalogued as COSV99927132; called by muse, mutect2
- LRP1 | c.13262T>C p.I4421T | Missense Mutation (SNP) | VAF 8/106 reads (8%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs140219533; called by muse, mutect2
- NIPAL4 | c.1283C>T p.P428L | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.879); catalogued as COSV99977794; called by muse, mutect2, varscan2
- SCNN1A | c.1177G>A p.D393N | Missense Mutation (SNP) | VAF 9/172 reads (5%) | SIFT tolerated (0.14); PolyPhen probably damaging (1); catalogued as rs886049758; ClinVar: uncertain significance; called by muse, mutect2
- TLR4 | c.1178A>G p.Q393R (on ENST00000355622 / NM_138554.5; = p.Q353R on NM_003266.4) | Missense Mutation (SNP) | VAF 18/159 reads (11%) | SIFT tolerated (0.37); PolyPhen benign (0.007); catalogued as COSV100842813; called by muse, mutect2, varscan2
- VPS13A | c.245T>C p.V82A | Missense Mutation (SNP) | VAF 12/170 reads (7%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.519); catalogued as COSV100653110; called by muse, mutect2
- ATRX | c.602_603insCT p.K202Lfs*5 | Frame Shift Ins (INS) | VAF 5/41 reads (12%) | called by mutect2, pindel
- CSMD1 | c.7617A>G p.Q2539= (on ENST00000520002; = p.Q2538= on NM_033225.6) | Silent (SNP) | VAF 5/12 reads (42%) | catalogued as COSV59388290; called by muse, mutect2, varscan2
- GNPTAB | c.1908G>A p.R636= | Silent (SNP) | VAF 39/106 reads (37%) | catalogued as COSV100172159; called by muse, mutect2, varscan2
- NIPAL4 | c.1122C>A p.I374= | Silent (SNP) | VAF 46/100 reads (46%) | catalogued as COSV99977792; called by muse, mutect2, varscan2
- OR10J5 | c.828G>A p.T276= | Silent (SNP) | VAF 48/113 reads (42%) | catalogued as rs368317841; called by muse, mutect2, varscan2
